Somatic mutation profile of tumor specimen MP2PRT-PASMAV-TMP1-A (aliquot MP2PRT-PASMAV-TMP1-A-1-0-D-A83O-36) from MP2PRT case MP2PRT-PASMAV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (921 days).
Specimen MP2PRT-PASMAV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 778fe906-d1b2-4114-bc37-31fbfb805120.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASMAV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASMAV-NB1-A-1-0-D-A83O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a29ea8b1-89b4-4b30-8366-597b1685db01

The open-access MAF lists 19 somatic variants for this specimen: 14 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 4, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1520C>A p.T507K | Missense Mutation (SNP) | VAF 126/367 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs886039463, CM090464, COSV104418166, COSV61005528; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EPHB1 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.118); catalogued as rs556035012, COSV67663308, COSV67663778; called by muse, mutect2, varscan2
- GABRA6 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 99/238 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs377669113; called by muse, mutect2, varscan2
- IGF2R | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 89/357 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1351477394; called by muse, mutect2, varscan2
- ITGA3 | c.2308C>T p.R770W | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.042); catalogued as rs200113398; called by muse, mutect2, varscan2
- KSR2 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 43/281 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs564650961, COSV60371482; called by muse, mutect2, varscan2
- MTHFD1L | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 90/487 reads (18%) | catalogued as rs543057137; called by muse, mutect2, varscan2
- OTOF | c.5623G>A p.V1875M (on ENST00000272371 / NM_194248.3; = p.V1108M on NM_004802.4) | Missense Mutation (SNP) | VAF 184/431 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.045); catalogued as rs370691004, COSV99719188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDHX | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 116/327 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as COSV57163975; called by muse, mutect2, varscan2
- SLC4A3 | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 41/401 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.892); catalogued as rs780258999, COSV56096226; called by muse, mutect2
- SPG7 | c.1775G>A p.R592Q (on ENST00000268704; = p.R599Q on NM_003119.4) | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149749852, CM134110, COSV99244690; called by muse, mutect2, varscan2
- CSKMT | c.706A>G p.I236V | Missense Mutation (SNP) | VAF 91/253 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LMF1 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- SCARA5 | c.64G>A p.D22N | Missense Mutation (SNP) | VAF 268/490 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1836C>T p.D612= | Silent (SNP) | VAF 183/1008 reads (18%) | catalogued as rs574416569, COSV61486012; called by muse, mutect2
- OLFML3 | c.348C>T p.G116= | Silent (SNP) | VAF 122/330 reads (37%) | catalogued as rs1328560042; called by muse, mutect2, varscan2
- PTPRH | c.3126C>T p.S1042= | Silent (SNP) | VAF 162/424 reads (38%) | catalogued as rs1361958096; called by muse, mutect2, varscan2
- ZNF532 | c.1887G>A p.K629= | Silent (SNP) | VAF 157/562 reads (28%) | catalogued as COSV100265923; called by muse, mutect2, varscan2
- KCTD1 | c.-15-45615C>T | Intron (SNP) | VAF 281/498 reads (56%) | called by muse, mutect2, varscan2
